Somatic mutation profile of cancer-model specimen HCM-BROD-0869-C43-85A (Adherent Cell Line, passage 11; aliquot HCM-BROD-0869-C43-85A-01D-A881-36), derived from the metastatic tumor of HCMI case HCM-BROD-0869-C43, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 45.7 years (16,703 days).
Specimen HCM-BROD-0869-C43-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 11.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 76f02bec-fc25-44b2-bcc9-613e278aebe4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0869-C43-10A (Blood Derived Normal), aliquot HCM-BROD-0869-C43-10A-01D-A881-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a2d001ad-cba3-4dc4-aaf1-9e17545a6376

The open-access MAF lists 135 somatic variants for this specimen: 84 protein-altering or splice-affecting, 47 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 76, Silent 47, Intron 4, Nonsense Mutation 4, Splice Region 2, In Frame Del 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EZH2 | c.1921T>A p.Y641N (on ENST00000460911 / NM_001203247.2; = p.Y646N on NM_004456.5) | Missense Mutation (SNP) | VAF 68/274 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.949); catalogued as rs267601395, COSV57445793, COSV57445823, COSV57462051; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.1043C>T p.P348L (on ENST00000272895 / NM_173076.3; = p.P30L on NM_015657.3) | Missense Mutation (SNP) | VAF 96/299 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs763523997, COSV99788163; called by muse, mutect2, varscan2
- AFTPH | c.358A>G p.M120V | Missense Mutation (SNP) | VAF 61/296 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs767615768; called by muse, mutect2, varscan2
- ANK3 | c.8932G>A p.G2978S | Missense Mutation (SNP) | VAF 101/267 reads (38%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.085); catalogued as COSV55060964; called by muse, mutect2, varscan2
- APCS | c.473C>T p.S158F | Missense Mutation (SNP) | VAF 160/583 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs866542574, COSV54818126; called by muse, mutect2, varscan2
- APOB | c.12136C>T p.R4046W | Missense Mutation (SNP) | VAF 115/336 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.599); catalogued as rs200222843; called by muse, mutect2, varscan2
- C2orf69 | c.26C>T p.S9L | Missense Mutation (SNP) | VAF 64/408 reads (16%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.011); catalogued as rs896102238; called by muse, mutect2, varscan2
- C5AR1 | c.56C>T p.T19I | Missense Mutation (SNP) | VAF 144/487 reads (30%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as rs1202047995, COSV61893625; called by muse, mutect2, varscan2
- CA13 | c.459A>C p.E153D | Missense Mutation (SNP) | VAF 34/228 reads (15%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as rs763563575; called by muse, mutect2, varscan2
- CALML5 | c.175G>A p.D59N | Missense Mutation (SNP) | VAF 247/654 reads (38%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.615); catalogued as rs1564480147; called by muse, mutect2
- CATSPER1 | c.509G>A p.G170D | Missense Mutation (SNP) | VAF 186/385 reads (48%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV56413574; called by muse, mutect2, varscan2
- CBX8 | c.295G>T p.A99S | Missense Mutation (SNP) | VAF 108/1330 reads (8%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV53935438; called by muse, mutect2
- CES3 | c.1331G>A p.R444Q | Missense Mutation (SNP) | VAF 73/387 reads (19%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.802); catalogued as rs769084788, COSV57594440; called by muse, mutect2, varscan2
- DNAH9 | c.6938A>G p.N2313S | Missense Mutation (SNP) | VAF 66/346 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); catalogued as COSV99307200; called by muse, mutect2, varscan2
- ERMN | c.565G>A p.D189N | Missense Mutation (SNP) | VAF 60/312 reads (19%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.714); catalogued as COSV68075248; called by muse, mutect2, varscan2
- GABRB1 | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 65/354 reads (18%) | SIFT tolerated (0.88); PolyPhen benign (0.017); catalogued as COSV54986020; called by muse, mutect2, varscan2
- HASPIN | c.2209C>T p.H737Y | Missense Mutation (SNP) | VAF 90/391 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.894); catalogued as rs1449370212, COSV99560912; called by muse, mutect2, varscan2
- ISX | c.384C>A p.I128= | Splice Region (SNP) | VAF 101/247 reads (41%) | catalogued as COSV58085991; called by muse, mutect2, varscan2
- KHDC1 | c.230G>A p.G77E (on ENST00000370384 / NM_001251874.2; = p.G4E on NM_030568.5) | Missense Mutation (SNP) | VAF 30/160 reads (19%) | SIFT tolerated (0.81); PolyPhen benign (0.017); catalogued as COSV57616157; called by muse, mutect2, varscan2
- LACRT | c.359G>A p.G120E | Missense Mutation (SNP) | VAF 60/278 reads (22%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.283); catalogued as COSV57688450; called by muse, mutect2, varscan2
- MRGPRX2 | c.146G>A p.G49E | Missense Mutation (SNP) | VAF 88/484 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.333); catalogued as COSV61674565; called by muse, mutect2, varscan2
- MUC21 | c.17G>A p.G6E | Missense Mutation (SNP) | VAF 103/355 reads (29%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.303); catalogued as rs267600948, COSV66221697; called by muse, mutect2, varscan2
- MYH2 | c.2632G>A p.E878K | Missense Mutation (SNP) | VAF 78/388 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.119); catalogued as rs745357669, COSV55431560; called by muse, mutect2, varscan2
- MYO15B | c.5999C>T p.T2000I | Missense Mutation (SNP) | VAF 98/978 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.14); catalogued as rs1479091818; called by muse, mutect2, varscan2
- MYT1 | c.1156G>A p.A386T | Missense Mutation (SNP) | VAF 148/1203 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs1224565423, COSV60505485; called by muse, mutect2, varscan2
- NLRC5 | c.5510C>T p.P1837L | Missense Mutation (SNP) | VAF 54/352 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as COSV52658449; called by muse, mutect2, varscan2
- NTN4 | c.436C>T p.R146C | Missense Mutation (SNP) | VAF 89/395 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1276288998; called by muse, mutect2, varscan2
- OR10G4 | c.791T>C p.M264T | Missense Mutation (SNP) | VAF 62/299 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.029); catalogued as COSV100304813; called by muse, varscan2
- OR2T34 | c.380G>A p.R127Q | Missense Mutation (SNP) | VAF 245/591 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.187); catalogued as rs374287459, COSV100170210; called by muse, mutect2, varscan2
- OR5H14 | c.397C>T p.P133S | Missense Mutation (SNP) | VAF 237/524 reads (45%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV101454206; called by muse, varscan2
- PATE3 | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 108/263 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV71323301; called by muse, mutect2, varscan2
- PDZRN4 | c.2805G>A p.M935I (on ENST00000402685 / NM_001164595.2; = p.M677I on NM_013377.4) | Missense Mutation (SNP) | VAF 80/338 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as COSV54211414; called by muse, mutect2, varscan2
- PRSS55 | c.877C>T p.L293F | Missense Mutation (SNP) | VAF 84/435 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as rs766342276, COSV60807662, COSV60808588; called by muse, mutect2, varscan2
- RIPK1 | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 34/356 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1279188189; called by muse, mutect2, varscan2
- RPTOR | c.2228G>C p.S743T | Missense Mutation (SNP) | VAF 64/442 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as rs1237481465; called by muse, mutect2, varscan2
- SERPINB3 | c.955G>A p.G319R | Missense Mutation (SNP) | VAF 29/537 reads (5%) | SIFT tolerated (0.48); PolyPhen benign (0.015); catalogued as rs577262694; called by muse, mutect2
- SLC35G2 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 216/325 reads (66%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.056); catalogued as rs780945551, COSV67588733; called by muse, mutect2, varscan2
- SNAP91 | c.2627C>T p.T876M | Missense Mutation (SNP) | VAF 54/223 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.474); catalogued as rs368296899; called by muse, mutect2, varscan2
- SPATA12 | c.188C>T p.A63V | Missense Mutation (SNP) | VAF 100/470 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs145406847; called by muse, mutect2, varscan2
- SPATA6 | c.787C>T p.P263S | Missense Mutation (SNP) | VAF 23/184 reads (13%) | SIFT tolerated (0.6); PolyPhen probably damaging (0.987); catalogued as COSV64057047; called by muse, mutect2, varscan2
- SPPL2B | c.1652C>T p.P551L | Missense Mutation (SNP) | VAF 120/543 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.084); catalogued as COSV101476099; called by muse, mutect2, varscan2
- STPG2 | c.736C>T p.R246* | Nonsense Mutation (SNP) | VAF 39/250 reads (16%) | catalogued as rs375848968, COSV54808861; called by muse, mutect2, varscan2
- TGM5 | c.1922T>C p.I641T (on ENST00000220420 / NM_201631.4; = p.I559T on NM_004245.4) | Missense Mutation (SNP) | VAF 62/449 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as rs200229745; called by muse, mutect2, varscan2
- TIAM1 | c.82C>T p.R28C | Missense Mutation (SNP) | VAF 77/507 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.745); catalogued as rs371962651; called by muse, mutect2, varscan2
- TMEM198 | c.764G>A p.R255Q | Missense Mutation (SNP) | VAF 70/373 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.449); catalogued as rs1251303878, COSV54727247, COSV54730004; called by muse, mutect2, varscan2
- TNP1 | c.154C>T p.R52C | Missense Mutation (SNP) | VAF 69/303 reads (23%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.928); catalogued as rs201394603, COSV52697111; called by muse, mutect2, varscan2
- VAMP7 | c.285G>T p.Q95H | Missense Mutation (SNP) | VAF 96/536 reads (18%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as COSV52901455; called by mutect2, varscan2
- ZNF497 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 229/831 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV54050590; called by muse, mutect2, varscan2
- ZNF679 | c.338G>A p.R113K | Missense Mutation (SNP) | VAF 29/214 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.058); catalogued as COSV55377102, COSV99739440; called by muse, mutect2, varscan2
- AC005833.1 | c.996G>T p.L332F | Missense Mutation (SNP) | VAF 68/539 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ACAN | c.2369C>A p.S790* | Nonsense Mutation (SNP) | VAF 108/583 reads (19%) | called by muse, mutect2, varscan2
- ACSM4 | c.1391A>T p.Y464F | Missense Mutation (SNP) | VAF 151/398 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CALCOCO2 | c.499del p.Q167Rfs*18 | Frame Shift Del (DEL) | VAF 50/383 reads (13%) | called by mutect2, pindel, varscan2
- CFAP53 | c.16T>C p.F6L | Missense Mutation (SNP) | VAF 74/415 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- CHD6 | c.6280G>C p.D2094H | Missense Mutation (SNP) | VAF 100/362 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- COL20A1 | c.3530G>A p.G1177E | Missense Mutation (SNP) | VAF 185/513 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CXCL5 | c.332A>T p.N111I | Missense Mutation (SNP) | VAF 45/312 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- DSC1 | c.2635C>T p.H879Y | Missense Mutation (SNP) | VAF 42/298 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.018); called by muse, varscan2
- EPHA7 | c.1791C>G p.Y597* | Nonsense Mutation (SNP) | VAF 43/214 reads (20%) | called by muse, mutect2, varscan2
- GAGE2A | c.110C>A p.P37Q | Missense Mutation (SNP) | VAF 49/457 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.329); called by muse, varscan2
- GPR39 | c.538C>A p.L180M | Missense Mutation (SNP) | VAF 20/590 reads (3%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2
- GUCA1A | c.486G>C p.K162N | Missense Mutation (SNP) | VAF 31/402 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.023); called by muse, mutect2
- HEPH | c.3238G>A p.E1080K (on ENST00000343002; = p.E813K on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 59/220 reads (27%) | SIFT tolerated (0.9); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- HR | c.3014A>T p.N1005I | Missense Mutation (SNP) | VAF 75/390 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HRH2 | c.745C>T p.P249S | Missense Mutation (SNP) | VAF 196/495 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HS3ST3A1 | c.962G>A p.G321E | Missense Mutation (SNP) | VAF 52/384 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.441); called by muse, varscan2
- KBTBD2 | c.1024A>G p.T342A | Missense Mutation (SNP) | VAF 47/336 reads (14%) | SIFT tolerated (0.96); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIF18B | c.2059C>G p.P687A (on ENST00000593135 / NM_001265577.2; = p.P699A on NM_001264573.2) | Missense Mutation (SNP) | VAF 103/745 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- LYPD6 | c.363T>A p.C121* | Nonsense Mutation (SNP) | VAF 54/256 reads (21%) | called by muse, mutect2, varscan2
- MAP2K1 | c.173_187del p.Q58_E62del | In Frame Del (DEL) | VAF 146/403 reads (36%) | called by mutect2, pindel, varscan2
- MUC16 | c.18037G>A p.E6013K | Missense Mutation (SNP) | VAF 91/429 reads (21%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- NRG1 | c.1016C>T p.S339F (on ENST00000405005 / NM_013964.5; = p.S344F on NM_013956.5) | Missense Mutation (SNP) | VAF 91/272 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- NUMA1 | c.1823C>T p.A608V | Missense Mutation (SNP) | VAF 168/416 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- OR9A2 | c.245G>T p.W82L | Missense Mutation (SNP) | VAF 105/730 reads (14%) | SIFT tolerated (0.68); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- PANX2 | c.1138C>T p.R380W | Missense Mutation (SNP) | VAF 112/774 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, varscan2
- PCDHB16 | c.547C>T p.H183Y | Missense Mutation (SNP) | VAF 132/516 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRDM8 | c.383T>G p.V128G | Missense Mutation (SNP) | VAF 45/395 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RLBP1 | c.795G>A p.R265= | Splice Region (SNP) | VAF 71/156 reads (46%) | called by muse, mutect2, varscan2
- SHOC1 | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 37/257 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- SLC6A18 | c.850G>A p.D284N | Missense Mutation (SNP) | VAF 97/378 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- SPATA25 | c.647G>A p.R216K | Missense Mutation (SNP) | VAF 85/826 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.059); called by muse, mutect2
- TLR3 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 47/314 reads (15%) | SIFT tolerated (0.55); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- UGT2B15 | c.856G>A p.A286T | Missense Mutation (SNP) | VAF 54/319 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- VARS2 | c.1945C>T p.P649S | Missense Mutation (SNP) | VAF 50/283 reads (18%) | SIFT tolerated (0.96); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- AOC3 | c.1251G>A p.L417= | Silent (SNP) | VAF 170/716 reads (24%) | called by muse, mutect2, varscan2
- COL11A2 | c.2568G>A p.G856= (on ENST00000341947 / NM_080680.3; = p.G749= on NM_080679.2) | Silent (SNP) | VAF 103/603 reads (17%) | called by muse, mutect2, varscan2
- COL4A5 | c.2109C>T p.I703= | Silent (SNP) | VAF 127/197 reads (64%) | catalogued as rs369092053; called by muse, mutect2, varscan2
- CTBP2 | c.1206C>T p.A402= | Silent (SNP) | VAF 60/257 reads (23%) | called by muse, mutect2, varscan2
- CTNND2 | c.84G>A p.T28= | Silent (SNP) | VAF 179/453 reads (40%) | catalogued as rs762650023, COSV58891330; called by muse, mutect2, varscan2
- DDAH2 | c.144G>T p.L48= | Silent (SNP) | VAF 139/731 reads (19%) | catalogued as COSV65384158; called by muse, mutect2, varscan2
- FAM186B | c.2211G>A p.T737= | Silent (SNP) | VAF 71/310 reads (23%) | catalogued as rs555752465; called by muse, mutect2, varscan2
- GBP2 | c.1635G>A p.E545= | Silent (SNP) | VAF 46/190 reads (24%) | called by muse, mutect2, varscan2
- GFPT2 | c.1113C>T p.I371= | Silent (SNP) | VAF 63/628 reads (10%) | called by muse, mutect2, varscan2
- GGT1 | c.1326C>T p.F442= | Silent (SNP) | VAF 58/383 reads (15%) | catalogued as rs1250375473, COSV50645173; called by muse, mutect2, varscan2
- GOLGB1 | c.8449T>C p.L2817= | Silent (SNP) | VAF 58/389 reads (15%) | called by muse, mutect2, varscan2
- IGHD1OR15-1B | c.16A>C p.*6= | Silent (SNP) | VAF 17/153 reads (11%) | called by muse, mutect2, varscan2
- IGHV1-46 | c.237C>T p.Y79= | Silent (SNP) | VAF 13/350 reads (4%) | catalogued as rs555653722; called by muse, mutect2
- IGLV1-44 | c.225C>T p.P75= | Silent (SNP) | VAF 64/480 reads (13%) | called by muse, mutect2, varscan2
- IVD | c.190C>T p.L64= (on ENST00000651168; = p.L61= on NM_002225.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 52/419 reads (12%) | catalogued as rs767318709; called by muse, mutect2
- LRRC2 | c.423G>A p.Q141= | Silent (SNP) | VAF 122/305 reads (40%) | called by muse, mutect2, varscan2
- MAPK8IP3 | c.1854G>A p.P618= | Silent (SNP) | VAF 97/636 reads (15%) | catalogued as rs766499121; called by muse, mutect2, varscan2
- METRN | c.672G>A p.Q224= | Silent (SNP) | VAF 344/724 reads (48%) | called by muse, mutect2, varscan2
- MMP2 | c.1575G>A p.E525= | Silent (SNP) | VAF 111/337 reads (33%) | called by muse, mutect2, varscan2
- MTNR1A | c.261G>A p.S87= | Silent (SNP) | VAF 125/343 reads (36%) | catalogued as rs773877086, COSV56154736; called by muse, mutect2, varscan2
- MYMK | c.360C>T p.G120= | Silent (SNP) | VAF 362/718 reads (50%) | catalogued as COSV101301187; called by muse, mutect2, varscan2
- NPY4R | c.240C>T p.I80= | Silent (SNP) | VAF 139/722 reads (19%) | catalogued as rs546342201, COSV100966155; called by muse, mutect2, varscan2
- OBSCN | c.7266G>A p.G2422= | Silent (SNP) | VAF 120/718 reads (17%) | catalogued as COSV52821390; called by mutect2, varscan2
- OR4N5 | c.768C>T p.F256= | Silent (SNP) | VAF 79/407 reads (19%) | called by muse, mutect2, varscan2
- PDZD2 | c.6276C>T p.I2092= | Silent (SNP) | VAF 199/568 reads (35%) | called by muse, mutect2, varscan2
- PES1 | c.741C>T p.P247= | Silent (SNP) | VAF 205/492 reads (42%) | catalogued as rs775880048; called by muse, mutect2, varscan2
- PLEKHG4B | c.2148G>A p.R716= (on ENST00000283426; = p.R1072= on NM_052909.5) | Silent (SNP) | VAF 295/698 reads (42%) | catalogued as COSV52047866; called by muse, mutect2, varscan2
- POGK | c.591C>T p.R197= | Silent (SNP) | VAF 43/679 reads (6%) | called by muse, mutect2
- POM121C | c.183G>A p.G61= | Silent (SNP) | VAF 66/516 reads (13%) | called by muse, mutect2, varscan2
- PRKACG | c.753C>T p.I251= | Silent (SNP) | VAF 94/613 reads (15%) | catalogued as COSV55248380; called by muse, mutect2, varscan2
- PRKDC | c.6135C>T p.F2045= | Silent (SNP) | VAF 64/415 reads (15%) | catalogued as rs781184930; called by muse, mutect2, varscan2
- PSD4 | c.63G>A p.L21= | Silent (SNP) | VAF 184/475 reads (39%) | called by muse, mutect2, varscan2
- PXDNL | c.2853C>T p.S951= | Silent (SNP) | VAF 100/498 reads (20%) | catalogued as rs1193456376; called by muse, mutect2, varscan2
- QRICH2 | c.3957C>T p.I1319= | Silent (SNP) | VAF 116/619 reads (19%) | catalogued as COSV53153100; called by muse, mutect2, varscan2
- SCN10A | c.1623G>A p.G541= | Silent (SNP) | VAF 83/650 reads (13%) | catalogued as rs757470309; called by muse, mutect2, varscan2
- SDAD1 | c.2061G>A p.K687= | Silent (SNP) | VAF 23/238 reads (10%) | catalogued as rs985659533; called by muse, mutect2, varscan2
- SGSH | c.834C>T p.F278= | Silent (SNP) | VAF 230/623 reads (37%) | called by muse, mutect2, varscan2
- SPOCK3 | c.999C>T p.L333= | Silent (SNP) | VAF 45/215 reads (21%) | catalogued as COSV100692928; called by muse, mutect2, varscan2
- SPTA1 | c.4068C>T p.I1356= | Silent (SNP) | VAF 157/546 reads (29%) | catalogued as rs1209643854, COSV100934109, COSV100934758, COSV63749559; called by muse, mutect2, varscan2
- SUSD1 | c.2124C>T p.S708= | Silent (SNP) | VAF 194/464 reads (42%) | called by muse, mutect2, varscan2
- TMEM130 | c.433C>T p.L145= | Silent (SNP) | VAF 161/439 reads (37%) | catalogued as COSV100229053; called by muse, mutect2, varscan2
- VCAN | c.7581C>T p.F2527= | Silent (SNP) | VAF 33/336 reads (10%) | catalogued as rs149880697; ClinVar: likely benign / benign; called by muse, mutect2, varscan2
- YRDC | c.600C>A p.S200= | Silent (SNP) | VAF 62/318 reads (19%) | called by muse, mutect2, varscan2
- ZAN | c.6657C>T p.N2219= | Silent (SNP) | VAF 68/504 reads (13%) | called by muse, mutect2, varscan2
- ZNF274 | c.249C>T p.T83= | Silent (SNP) | VAF 137/470 reads (29%) | catalogued as COSV100465526; called by muse, mutect2, varscan2
- ZNF408 | c.1047G>A p.Q349= | Silent (SNP) | VAF 83/498 reads (17%) | catalogued as rs1302788412; called by muse, mutect2, varscan2
- ZNF763 | c.1062C>T p.S354= (on ENST00000358987 / NM_001367172.2; = p.S357= on NM_001012753.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 78/356 reads (22%) | called by muse, mutect2, varscan2
- DCAF6 | c.1378+11026C>T | Intron (SNP) | VAF 106/422 reads (25%) | catalogued as rs772191895, COSV100395009; called by muse, mutect2, varscan2
- RIMBP2 | c.2362-1733C>T | Intron (SNP) | VAF 75/365 reads (21%) | called by muse, mutect2, varscan2
- TRIM54 | c.513+120G>A | Intron (SNP) | VAF 93/273 reads (34%) | called by muse, mutect2, varscan2
- ZIC4 | c.-15-1280C>T | Intron (SNP) | VAF 195/312 reads (63%) | called by muse, mutect2, varscan2
